Gene-level copy-number profile of tumor specimen TCGA-HQ-A5ND-01A from TCGA case TCGA-HQ-A5ND, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 78.2 years (28,555 days).
Specimen TCGA-HQ-A5ND-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.d1822035-1f77-4e19-8915-9bf9062f8a4c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HQ-A5ND-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6c0703d7-ca76-4944-be05-8b62226ee4e6

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 2,029; copy number 2: 11,630; copy number 3: 25,320; copy number 4: 13,703; copy number 5: 5,072; copy number 6: 1,362; copy number 7: 353; copy number 8: 3; copy number 9: 22; copy number 11: 70; copy number 13: 65; copy number 15: 169.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HQ-A5ND-01A-11D-A26L-01): tumor purity 0.63, ploidy 3.22, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:167,116,318–167,168,401, 2 genes: AC091819.2, AC091819.1.
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–3): AL359922.1.
- chr9:21,929,457–22,824,213, 12 genes (within-gene range 0–3): ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239.
- chr9:22,747,700–22,768,316, 2 genes: CLIC4P1, AC017067.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 682 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:158,930,796–162,868,815, 169 genes, copy number 15 (broad region; genes not listed).
- chr5:20,606,710–45,895,970, 353 genes, copy number 7 (broad region; genes not listed).
- chr11:69,294,151–71,423,423, 47 genes, copy number 13 (within-gene range 2–13): MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3, MIR3664, AP003783.1, ACTE1P.
- chr11:92,161,106–94,740,355, 70 genes, copy number 11 (broad region; genes not listed).
- chr11:115,128,218–115,843,146, 18 genes, copy number 13: AP003179.1, CADM1, AP000465.1, AP000462.3, AP000462.1, AP000462.2, AP003174.2, AP003174.3, RPL12P46, AP003174.1, AP000997.1, AP000997.2, AP000997.3, AP000997.4, LINC02698, AP002991.1, AP002991.2, LINC00900.
- chr14:81,741,002–82,030,349, 1 gene, copy number 8 (within-gene range 3–8): AL355838.1.
- chr14:81,916,231–82,430,156, 2 genes, copy number 8: EIF3LP1, Metazoa_SRP.
- chr14:83,017,106–86,161,500, 22 genes, copy number 9 (within-gene range 3–9): AL359238.1, AL162872.1, RNU7-51P, RNU6ATAC28P, AL161713.1, LINC02305, AL356807.1, MTND4P33, MTND5P35, MTCYBP27, RNU6-976P, AL163642.1, AL163642.2, AL357172.1, AL049775.2, LINC02329, LINC00911, AL049775.1, AL049775.3, FLRT2, LINC02328, LINC02316.

Autosomal genes at a single copy (total copy number 1): 713. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
